Somatic mutation profile of tumor specimen TCGA-DX-A6YV-01A (aliquot TCGA-DX-A6YV-01A-12D-A351-09) from TCGA case TCGA-DX-A6YV, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 74.1 years (27,053 days).
Specimen TCGA-DX-A6YV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5fe58f42-fd3a-43c9-8b4f-6f8e1f182cfb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A6YV-10B (Blood Derived Normal), aliquot TCGA-DX-A6YV-10B-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c97c0a3b-e78b-4fda-8a79-e68d42c1765f

The open-access MAF lists 256 somatic variants for this specimen: 213 protein-altering or splice-affecting, 36 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 204, Silent 36, Intron 4, Nonsense Mutation 4, Splice Site 4, 5'Flank 1, Nonstop Mutation 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.607+1_607+2del p.X203_splice | Splice Site (DEL) | VAF 25/35 reads (71%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- SCN4A | c.2024G>A p.R675Q | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs121908557, CM043572, COSV101438657, COSV99076872; ClinVar: pathogenic; called by muse, varscan2
- ABCA12 | c.2378C>A p.A793D (on ENST00000272895 / NM_173076.3; = p.A475D on NM_015657.3) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.663); catalogued as COSV99792033; called by mutect2, varscan2
- ABCA12 | c.952C>T p.H318Y | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.062); catalogued as rs753139272, COSV99792035; called by muse, mutect2, varscan2
- ABCB5 | c.2441G>T p.G814V (on ENST00000404938 / NM_001163941.2; = p.G369V on NM_178559.6) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99329678; called by mutect2, varscan2
- ABCG1 | c.735-1G>T p.X245_splice | Splice Site (SNP) | VAF 8/88 reads (9%) | catalogued as COSV100494526; called by muse, mutect2
- ACLY | c.2417C>A p.A806D | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100709908; called by mutect2, varscan2
- ADAMTS12 | c.1813C>A p.Q605K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.416); catalogued as COSV100711690; called by muse, varscan2
- ADGRD1 | c.1800G>T p.Q600H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99897091; called by mutect2, varscan2
- AMOTL1 | c.1267G>T p.A423S | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100504741; called by mutect2, varscan2
- ANK2 | c.1315G>T p.A439S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.622); catalogued as COSV100004251; called by mutect2, varscan2
- ANTXR2 | c.225C>A p.S75R | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99786840; called by mutect2, varscan2
- AP1G2 | c.473C>A p.A158D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100437032; called by mutect2, varscan2
- APC | c.6156G>T p.K2052N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as COSV99970255; called by mutect2, varscan2
- ARFGEF2 | c.223G>T p.A75S | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100904479; called by mutect2, varscan2
- ARHGAP21 | c.2099C>A p.A700D | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.038); catalogued as COSV100256673; called by muse, mutect2
- ARHGAP35 | c.1485G>T p.L495F | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101351710; called by muse, mutect2, varscan2
- ASXL1 | c.968G>T p.R323L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100041143; called by muse, mutect2, varscan2
- ATP6V1B2 | c.381G>T p.M127I | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV99369600; called by muse, mutect2, varscan2
- BAG6 | c.3335C>A p.A1112D (on ENST00000676571; = p.A1065D on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV99277633; called by mutect2, varscan2
- BAZ2B | c.5186C>A p.A1729D | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV100601013; called by mutect2, varscan2
- BMP6 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1306853486, COSV51661769; called by muse, mutect2, varscan2
- BST1 | c.353G>T p.S118I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs1340732559, COSV99400148; called by mutect2, varscan2
- C11orf54 | c.245A>G p.K82R | Missense Mutation (SNP) | VAF 68/126 reads (54%) | SIFT tolerated (0.38); PolyPhen benign (0.034); catalogued as COSV100487120; called by muse, mutect2, varscan2
- C12orf40 | c.1469G>T p.S490I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100210779; called by mutect2, varscan2
- C1orf141 | c.182C>A p.A61E | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV100924392; called by muse, varscan2
- C2orf16 | c.940C>A p.Q314K | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.303); catalogued as COSV101284424; called by muse, mutect2, varscan2
- CASD1 | c.2161G>T p.A721S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99803082; called by muse, mutect2, varscan2
- CCDC173 | c.427C>A p.Q143K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.339); catalogued as COSV101352370; called by muse, varscan2
- CCDC88A | c.3916C>A p.L1306M | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); catalogued as COSV99711203; called by mutect2, varscan2
- CD14 | c.890C>A p.A297D | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.09); catalogued as COSV57369979; called by mutect2, varscan2
- CD22 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as COSV99323770; called by mutect2, varscan2
- CELF5 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99486192; called by mutect2, varscan2
- CEP162 | c.2958C>A p.S986R | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100003410; called by muse, mutect2
- CEP192 | c.4488G>T p.E1496D | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100382145; called by muse, varscan2
- CETP | c.167G>T p.S56I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.364); catalogued as COSV99570349; called by mutect2, varscan2
- CLEC9A | c.548G>T p.S183I | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.694); catalogued as COSV100191746; called by muse, mutect2
- CNOT1 | c.271C>A p.L91M | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV100410080; called by muse, varscan2
- CNTN6 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 59/103 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752027829, COSV63161676; called by muse, varscan2
- COG1 | c.2619+2T>A p.X873_splice | Splice Site (SNP) | VAF 42/123 reads (34%) | catalogued as COSV100245451; called by muse, mutect2, varscan2
- COL11A1 | c.1553C>A p.A518D | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100618050; called by muse, mutect2, varscan2
- COL6A5 | c.6025G>T p.A2009S (on ENST00000312481; = p.A2005S on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99594545; called by muse, varscan2
- CORO1C | c.1114C>A p.L372M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.353); catalogued as COSV99776234; called by muse, varscan2
- CORO2A | c.1393C>A p.L465M | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV100674144; called by mutect2, varscan2
- CPO | c.122G>T p.S41I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99786666; called by mutect2, varscan2
- CSF3R | c.1292C>A p.A431D | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV100118250; called by mutect2, varscan2
- CSNK1A1 | c.155C>A p.A52D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.892); catalogued as COSV99939815; called by mutect2, varscan2
- CTC1 | c.3395C>A p.A1132D | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); catalogued as COSV100236795; called by muse, mutect2
- CUL9 | c.2386G>T p.A796S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.311); catalogued as COSV52735574, COSV99336062; called by mutect2, varscan2
- DEFA5 | c.56C>A p.A19D | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100400498; called by muse, mutect2, varscan2
- DENND2A | c.2362C>A p.L788M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as COSV99327012; called by muse, mutect2, varscan2
- DEUP1 | c.350A>G p.Q117R | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs530048912, COSV99977632; called by muse, mutect2, varscan2
- DHX37 | c.138C>A p.S46R | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100439508; called by mutect2, varscan2
- DMGDH | c.1420C>A p.L474I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.02); catalogued as COSV99669529; called by mutect2, varscan2
- DNASE1L3 | c.328C>A p.L110M | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.216); catalogued as COSV100568852; called by mutect2, varscan2
- DOCK10 | c.5006C>A p.A1669D | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV99291654; called by mutect2, varscan2
- DOCK3 | c.3952G>T p.A1318S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99815102; called by mutect2, varscan2
- DYNC1LI2 | c.458C>A p.A153D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99263272; called by mutect2, varscan2
- DYNC2H1 | c.535T>C p.W179R | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM130540, COSV100519749; called by muse, varscan2
- DYRK2 | c.372G>T p.E124D (on ENST00000344096 / NM_006482.3; = p.E51D on NM_003583.4) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV100165407; called by mutect2, varscan2
- DYSF | c.2188A>G p.T730A | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.04); catalogued as COSV99250412; called by muse, mutect2, varscan2
- ECT2L | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.368); catalogued as COSV100872192; called by muse, mutect2
- EDRF1 | c.1797G>T p.E599D (on ENST00000356792 / NM_001202438.2; = p.E565D on NM_015608.2) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV100524019; called by mutect2, varscan2
- EFNA5 | c.358C>A p.L120I | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.925); catalogued as COSV100322078; called by muse, varscan2
- EID1 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as COSV100195350; called by mutect2, varscan2
- EPHA5 | c.2767C>A p.P923T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56639646, COSV99901276; called by mutect2, varscan2
- EPHB4 | c.275T>G p.F92C | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100639656; called by muse, varscan2
- FAN1 | c.2134G>T p.A712S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100756101; called by mutect2, varscan2
- FAT2 | c.13007T>C p.M4336T | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as COSV99944118; called by muse, varscan2
- FEM1C | c.1139C>A p.A380D | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.282); catalogued as COSV99174427; called by mutect2, varscan2
- FGD5 | c.778G>T p.A260S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.057); catalogued as COSV99547539; called by muse, mutect2, varscan2
- FGG | c.890C>A p.A297D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.229); catalogued as COSV100272082; called by mutect2, varscan2
- FLG | c.11552C>T p.A3851V | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs150496930; called by muse, varscan2
- FRAS1 | c.2918G>T p.C973F | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99355827; called by muse, mutect2
- HABP2 | c.1676G>T p.G559V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV100667816; called by muse, mutect2, varscan2
- HELZ2 | c.2036C>A p.T679N (on ENST00000467148 / NM_001037335.2; = p.T110N on NM_033405.3) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as COSV100915705; called by muse, mutect2, varscan2
- HR | c.781C>A p.Q261K | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV100456035; called by muse, mutect2, varscan2
- HSPBAP1 | c.765G>A p.W255* | Nonsense Mutation (SNP) | VAF 84/86 reads (98%) | catalogued as COSV100063745; called by muse, mutect2, varscan2
- IFT80 | c.2045C>A p.A682D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as COSV100425136; called by mutect2, varscan2
- IP6K2 | c.931C>A p.L311M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99584258; called by mutect2, varscan2
- ITPR1 | c.4986G>T p.Q1662H (on ENST00000354582; = p.Q1647H on NM_002222.7) | Missense Mutation (SNP) | VAF 14/185 reads (8%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.771); catalogued as COSV100233216; called by muse, mutect2
- JPH3 | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.347); catalogued as COSV99414032; called by mutect2, varscan2
- KCNH3 | c.625G>T p.A209S | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.143); catalogued as COSV57789949, COSV99235804; called by muse, mutect2
- KIF17 | c.2812C>A p.L938I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.07); catalogued as COSV99929779; called by mutect2, varscan2
- KIF9 | c.2254C>A p.Q752K (on ENST00000265529 / NM_001377474.1; = p.Q687K on NM_022342.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as COSV99647030; called by muse, mutect2, varscan2
- KIFC3 | c.1940C>A p.S647* | Nonsense Mutation (SNP) | VAF 3/20 reads (15%) | catalogued as COSV65551011; called by muse, mutect2, varscan2
- KLF10 | c.449C>A p.A150D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99574950; called by mutect2, varscan2
- KLHL38 | c.355C>A p.L119M | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as rs865868815, COSV100384588; called by mutect2, varscan2
- L3MBTL4 | c.1417G>C p.D473H | Missense Mutation (SNP) | VAF 35/37 reads (95%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.827); catalogued as COSV99531157; called by muse, mutect2, varscan2
- LAG3 | c.541G>T p.A181S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99180015; called by mutect2, varscan2
- LAMC1 | c.3075G>T p.W1025C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.738); catalogued as COSV99280427; called by mutect2, varscan2
- LARGE1 | c.578C>A p.A193D | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.196); catalogued as COSV100506358; called by mutect2, varscan2
- LIPH | c.419C>A p.A140E | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV99956331; called by muse, mutect2, varscan2
- LRCH4 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as rs1245763705, COSV53823723; called by muse, mutect2, varscan2
- LRP1 | c.3869G>T p.S1290I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV99677232; called by mutect2, varscan2
- MACF1 | c.19602G>T p.Q6534H (on ENST00000372915; = p.Q4579H on NM_012090.5) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as COSV99246907; called by mutect2, varscan2
- MAD2L1BP | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs985221164, COSV100938765; called by muse, mutect2
- MAGEC3 | c.1729-1G>T p.X577_splice | Splice Site (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100026129; called by mutect2, varscan2
- MCF2L | c.2705C>T p.T902M (on ENST00000375608; = p.T870M on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770639443, COSV56182559; called by muse, varscan2
- MED12 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.78); catalogued as COSV100379969, COSV61350171; called by mutect2, varscan2
- MGAM | c.3610A>G p.T1204A | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV101527753; called by muse, mutect2, varscan2
- MICU3 | c.904G>T p.A302S | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100536595; called by muse, mutect2, varscan2
- MRGPRF | c.457C>A p.R153S | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.158); catalogued as COSV100307927, COSV57995824; called by muse, mutect2
- MRGPRX3 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.079); catalogued as rs749858617, COSV66934736; called by mutect2, varscan2
- MRPS27 | c.847C>A p.L283M | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV99782503; called by mutect2, varscan2
- MST1R | c.1999C>A p.H667N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as COSV56565384, COSV99619696; called by muse, mutect2, varscan2
- MYO18A | c.5540G>A p.R1847H | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs912902267, COSV100572736; called by muse, mutect2, varscan2
- NAV3 | c.4858G>T p.A1620S | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.219); catalogued as COSV57062774; called by mutect2, varscan2
- NECTIN2 | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.247); catalogued as COSV99375271; called by mutect2, varscan2
- NEUROD6 | c.587C>A p.A196D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.073); catalogued as rs1001962404, COSV51773762; called by mutect2, varscan2
- NEXMIF | c.3698A>G p.N1233S | Missense Mutation (SNP) | VAF 36/36 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99281920; called by muse, mutect2, varscan2
- NFATC4 | c.1313G>T p.S438I | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99151125; called by mutect2, varscan2
- NFKB1 | c.2907G>T p.*969Yext*25 (on ENST00000394820 / NM_001382627.1; = p.*970Yext*25 on NM_003998.4 and 2 other RefSeq transcripts) | Nonstop Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99897881; called by mutect2, varscan2
- NKTR | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV51770949, COSV99236362; called by mutect2, varscan2
- NLRP10 | c.866T>C p.L289P | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100149978; called by muse, mutect2, varscan2
- NPAP1 | c.2839G>C p.E947Q | Missense Mutation (SNP) | VAF 20/20 reads (100%) | SIFT tolerated (0.38); PolyPhen benign (0.094); catalogued as COSV100276201; called by muse, mutect2
- NPRL3 | c.353C>A p.A118E | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.97); PolyPhen benign (0.077); catalogued as COSV101302112; called by muse, mutect2, varscan2
- NUP54 | c.20C>A p.A7D | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV99345310, COSV99345490; called by mutect2, varscan2
- NUP62 | c.923C>A p.A308D | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV100352358; called by mutect2, varscan2
- OBSCN | c.19012G>T p.E6338* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV99484319; called by muse, mutect2, varscan2
- OLFML2B | c.935A>T p.D312V | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as COSV99668936; called by muse, mutect2, varscan2
- OR10G8 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1252667661, COSV101461882, COSV70908407; called by muse, mutect2, varscan2
- OSBPL10 | c.908C>A p.A303E | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as COSV101159864, COSV67340456; called by mutect2, varscan2
- PABPC1L | c.1579G>T p.A527S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV99408181; called by mutect2, varscan2
- PADI1 | c.506G>T p.S169I | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.113); catalogued as COSV100969281; called by mutect2, varscan2
- PALLD | c.1225G>T p.A409S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.437); catalogued as COSV99825830; called by muse, mutect2, varscan2
- PAQR8 | c.677G>T p.S226I | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100658534; called by mutect2, varscan2
- PCDHGA7 | c.2242G>A p.A748T | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.251); catalogued as rs1183220869, COSV99547017; called by muse, mutect2, varscan2
- PDCD11 | c.1053G>T p.Q351H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100874419; called by mutect2, varscan2
- PDE1C | c.167C>A p.A56D | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100373850; called by muse, mutect2
- PHF21A | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.186); catalogued as COSV99139374; called by muse, mutect2, varscan2
- PHLDB3 | c.1276C>A p.P426T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.057); catalogued as COSV99416022; called by mutect2, varscan2
- PHRF1 | c.4704G>T p.E1568D (on ENST00000264555 / NM_001286581.2; = p.E1567D on NM_020901.4) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99213464; called by mutect2, varscan2
- PIWIL1 | c.1894G>A p.D632N | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV55348075; called by muse, mutect2, varscan2
- PLCB4 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99596962; called by muse, mutect2, varscan2
- PLEKHM3 | c.1907T>G p.L636R | Missense Mutation (SNP) | VAF 48/54 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101216880; called by muse, mutect2, varscan2
- PPFIA3 | c.1681G>T p.A561S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV61953866; called by muse, mutect2, varscan2
- PPP1R18 | c.1687C>A p.L563M | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV99223924; called by muse, mutect2
- PRKAA1 | c.46C>A p.Q16K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV99713424; called by muse, mutect2, varscan2
- PTPRS | c.4867C>A p.L1623I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99512479; called by mutect2, varscan2
- RABEP1 | c.2469G>T p.K823N | Missense Mutation (SNP) | VAF 12/235 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV99337015; called by muse, mutect2
- RAPGEF1 | c.2959C>A p.L987M | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100940771; called by muse, mutect2
- RASAL3 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs761696731, COSV52996868; called by muse, mutect2, varscan2
- RPL7 | c.668A>G p.K223R | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as COSV99536366; called by muse, mutect2
- RRP12 | c.3781C>A p.L1261I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100213493; called by mutect2, varscan2
- RYR3 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as COSV66803712; called by muse, varscan2
- SAFB2 | c.1174C>A p.P392T | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.9); PolyPhen benign (0.444); catalogued as COSV99386110; called by mutect2, varscan2
- SCFD2 | c.329C>A p.A110D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.203); catalogued as COSV101189472, COSV66373780; called by mutect2, varscan2
- SEC24D | c.2677C>A p.H893N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.18); catalogued as COSV54878110; called by mutect2, varscan2
- SEL1L | c.638C>A p.A213E | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100378109; called by muse, mutect2
- SEMA3D | c.2311C>A p.L771I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99407427; called by mutect2, varscan2
- SEMA4A | c.1235G>T p.G412V | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); catalogued as COSV100740741; called by muse, mutect2
- SERPINA5 | c.652A>G p.T218A | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1263664719, COSV100291822; called by muse, mutect2, varscan2
- SI | c.2702C>A p.A901D | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1405462436, COSV100017189; called by muse, mutect2, varscan2
- SLC26A9 | c.1928C>A p.A643D | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.023); catalogued as COSV100536772; called by mutect2, varscan2
- SLC2A4 | c.54G>T p.Q18H | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV99142829; called by muse, mutect2, varscan2
- SLC30A9 | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.079); catalogued as COSV100048517; called by mutect2, varscan2
- SLC6A4 | c.854C>A p.A285D | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99911608; called by mutect2, varscan2
- SMG1 | c.7918C>A p.Q2640K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as COSV101246852; called by muse, mutect2
- SMG1 | c.4550C>A p.A1517D | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.039); catalogued as COSV101246855; called by mutect2, varscan2
- SUZ12 | c.276G>T p.K92N | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100497097; called by muse, varscan2
- SVEP1 | c.1568C>T p.T523M | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs778809311, COSV100238601; called by muse, varscan2
- SYCP2L | c.2178G>T p.K726N | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.571); catalogued as COSV99305857; called by mutect2, varscan2
- TALDO1 | c.742G>T p.A248S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV100032884; called by mutect2, varscan2
- TEP1 | c.3702C>A p.S1234R | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.055); catalogued as COSV52997272; called by muse, varscan2
- TLCD4 | c.576G>T p.M192I | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100930790; called by muse, mutect2
- TLR5 | c.1678C>A p.L560I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); catalogued as COSV100643389; called by mutect2, varscan2
- TM6SF1 | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99362885; called by mutect2, varscan2
- TMEM43 | c.801G>T p.Q267H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100044572; called by mutect2, varscan2
- TMEM45A | c.196G>T p.A66S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as COSV60254557; called by mutect2, varscan2
- TRIP12 | c.1083C>A p.S361R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV99390942; called by muse, varscan2
- TRMT1L | c.359C>A p.A120D | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.023); catalogued as COSV100834756; called by muse, mutect2, varscan2
- TSC1 | c.2450C>A p.A817D | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100052608; called by muse, mutect2, varscan2
- TTLL4 | c.2399G>T p.S800I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99293754; called by mutect2, varscan2
- TTLL9 | c.111G>T p.E37D | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100207278; called by mutect2, varscan2
- TTN | c.91110A>G p.I30370M (on ENST00000591111; = p.I22946M on NM_003319.4) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | PolyPhen benign (0.022); catalogued as COSV100630228; called by muse, mutect2, varscan2
- UBE2M | c.475C>A p.L159M | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV99448365; called by mutect2, varscan2
- UMODL1 | c.2993T>A p.V998E (on ENST00000408910 / NM_001004416.2; = p.V1126E on NM_173568.3) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV101252719; called by muse, mutect2, varscan2
- USH2A | c.14681C>A p.A4894D | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.856); catalogued as COSV100242704; called by mutect2, varscan2
- USP26 | c.1100C>A p.A367D | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); catalogued as COSV100896760, COSV100896763; called by mutect2, varscan2
- USP36 | c.2651C>A p.A884D | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); catalogued as COSV100361411, COSV100361833; called by mutect2, varscan2
- VEPH1 | c.628C>A p.L210M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100748052; called by mutect2, varscan2
- VIP | c.196G>T p.A66S | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV100923969; called by muse, mutect2
- VWA8 | c.2615C>A p.A872E | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV99865174; called by mutect2, varscan2
- VWCE | c.775G>A p.V259M | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as rs779785266, COSV100076161; called by muse, mutect2, varscan2
- WTAP | c.766G>T p.A256S | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100603411; called by muse, mutect2, varscan2
- XRCC1 | c.42C>A p.S14R | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99486748; called by mutect2, varscan2
- ZDHHC8 | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100273217; called by mutect2, varscan2
- ZFHX3 | c.6817G>C p.E2273Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99214703; called by muse, mutect2, varscan2
- ZNF451 | c.2888G>T p.G963V (on ENST00000370706 / NM_001031623.3; = p.G915V on NM_015555.2) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62596431; called by mutect2, varscan2
- ZNF813 | c.1441G>T p.A481S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as rs370608213; called by mutect2, varscan2
- ABHD3 | c.1081C>A p.Q361K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, varscan2
- ALDH1L2 | c.920C>A p.A307E | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.102); called by mutect2, varscan2
- ARHGEF15 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2
- BOD1L1 | c.2323C>A p.Q775K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.078); called by muse, varscan2
- CD7 | c.697C>A p.L233M | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.021); called by muse, mutect2
- DGKQ | c.2255C>A p.A752E | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DZIP1 | c.2495C>A p.A832E (on ENST00000347108; = p.A813E on NM_014934.5) | Missense Mutation (SNP) | VAF 10/181 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- FAP | c.2147C>A p.A716D | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- GIN1 | c.743C>A p.A248E | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.014); called by muse, mutect2
- HDAC7 | c.1524C>A p.S508R (on ENST00000427332; = p.S547R on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- IGHA1 | c.733C>A p.L245M | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.873); called by mutect2, varscan2
- IGHV3-20 | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by mutect2, varscan2
- ITPR3 | c.6072G>T p.E2024D | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- LNPEP | c.1177G>T p.A393S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, varscan2
- MORN3 | c.243C>A p.D81E | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.11); called by muse, varscan2
- MSI2 | c.243G>T p.Q81H | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.178); called by muse, mutect2
- PELP1 | c.711_712del p.C237* | Nonsense Mutation (DEL) | VAF 44/136 reads (32%) | called by pindel, varscan2
- PRKCH | c.895G>T p.A299S | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.005); called by muse, mutect2
- RPL3L | c.892C>A p.L298M | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2
- UBR4 | c.5794C>A p.Q1932K | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2
- WNK1 | c.5724G>T p.E1908D (on ENST00000315939 / NM_018979.4; = p.E1660D on NM_014823.3) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0); called by mutect2, varscan2
- WWC2 | c.632G>T p.S211I | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.806); called by mutect2, varscan2
- ABCB10 | c.729T>A p.I243= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV100748071; called by muse, mutect2, varscan2
- AK1 | c.363C>A p.G121= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV99802477; called by mutect2, varscan2
- AKAP13 | c.6597G>T p.V2199= (on ENST00000394518 / NM_007200.5; = p.V2203= on NM_006738.6) | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100774698; called by muse, mutect2, varscan2
- AQP11 | c.258G>T p.S86= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100547402; called by mutect2, varscan2
- ARRDC1 | c.1035G>T p.L345= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100604278; called by muse, varscan2
- B4GALNT4 | c.1182G>T p.P394= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV100327871; called by muse, mutect2
- BARX2 | c.288A>G p.A96= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as COSV99859025; called by muse, mutect2, varscan2
- BSG | c.225G>T p.R75= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100345025; called by mutect2, varscan2
- CARMIL1 | c.3465G>T p.G1155= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100278826; called by mutect2, varscan2
- CSMD1 | c.4884C>A p.G1628= (on ENST00000520002; = p.G1627= on NM_033225.6) | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs781401362, COSV100153748; called by mutect2, varscan2
- EPPK1 | c.4356C>T p.A1452= | Silent (SNP) | VAF 17/18 reads (94%) | catalogued as COSV101599955; called by muse, mutect2, varscan2
- FAM169A | c.630G>A p.A210= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs768881317, COSV65846105; called by mutect2, varscan2
- FZD9 | c.1494G>A p.S498= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs782046803, COSV100290149; called by mutect2, varscan2
- GPR171 | c.336C>A p.R112= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99854707; called by mutect2, varscan2
- GPRC5D | c.558C>T p.F186= | Silent (SNP) | VAF 34/48 reads (71%) | catalogued as rs567902391, COSV99964324; called by muse, mutect2, varscan2
- GRIN2A | c.306C>T p.D102= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs200850130; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- IRAK2 | c.180G>T p.L60= | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as rs1437092889; called by muse, mutect2
- KDR | c.1962C>T p.C654= | Silent (SNP) | VAF 21/34 reads (62%) | catalogued as rs544591377, COSV55774458, COSV99818699; called by muse, mutect2, varscan2
- LMTK2 | c.3990G>T p.L1330= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV52002301; called by mutect2, varscan2
- MMP13 | c.60G>A p.L20= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV99506872; called by muse, mutect2, varscan2
- MMP16 | c.153C>A p.G51= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99690405; called by mutect2, varscan2
- MMP19 | c.1335C>A p.G445= | Silent (SNP) | VAF 6/65 reads (9%) | called by muse, mutect2
- OR4C15 | c.33T>C p.N11= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as COSV100116103; called by muse, mutect2, varscan2
- OSM | c.120C>A p.G40= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV53162034; called by mutect2, varscan2
- PIK3CD | c.1185C>T p.Y395= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as rs769070246, COSV100740536; called by muse, mutect2, varscan2
- PRUNE2 | c.7074C>A p.G2358= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV100945140; called by mutect2, varscan2
- QDPR | c.147C>T p.S49= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs758659025, COSV99845956; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAPGEF3 | c.12C>A p.G4= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV99406859; called by mutect2, varscan2
- SLC17A7 | c.498C>A p.R166= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV55546745, COSV99677069; called by mutect2, varscan2
- SLC37A2 | c.1356G>T p.G452= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV100017486; called by mutect2, varscan2
- SPOCK2 | c.885C>A p.G295= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV100436488; called by mutect2, varscan2
- TRAJ26 | c.54G>T p.V18= | Silent (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- TULP2 | c.849C>A p.G283= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs1200475427, COSV99668098; called by muse, mutect2, varscan2
- UNC45B | c.2433G>T p.L811= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV99269231; called by mutect2, varscan2
- ZNF35 | c.441T>C p.P147= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as COSV99940178; called by muse, mutect2
- ZNF629 | c.900C>A p.G300= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV99355027; called by mutect2, varscan2
- AC073310.1 | n.211G>T | RNA (SNP) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- DST | c.4297-2576C>A | Intron (SNP) | VAF 6/54 reads (11%) | catalogued as COSV99760040, COSV99760328; called by mutect2, varscan2
- LBX2 | chr2:74502699 G>T | 5'Flank (SNP) | VAF 5/50 reads (10%) | catalogued as COSV99283434; called by muse, mutect2, varscan2
- PCM1 | c.783+223G>T | Intron (SNP) | VAF 4/30 reads (13%) | catalogued as rs527876600, COSV100279620; called by mutect2, varscan2
- PCSK7 | c.*1636C>A | 3'UTR (SNP) | VAF 5/48 reads (10%) | catalogued as COSV99639220; called by mutect2, varscan2
- PIK3C2B | c.934-1580C>A | Intron (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- RORA | c.196+51306C>A | Intron (SNP) | VAF 4/28 reads (14%) | catalogued as COSV55035148; called by muse, mutect2, varscan2
